Somatic mutation profile of tumor specimen TCGA-DU-6406-01A (aliquot TCGA-DU-6406-01A-11D-1705-08) from TCGA case TCGA-DU-6406, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.2 years (21,634 days).
Specimen TCGA-DU-6406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 356b9e5e-1d26-47c4-9ec2-94b79d17d455.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6406-10A (Blood Derived Normal), aliquot TCGA-DU-6406-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a59e2b5-9c5f-40c0-b0b4-782d003da473

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COP1 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100443364; called by muse, mutect2, varscan2
- MX2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs867413932, COSV58095491; called by muse, mutect2, varscan2
- MYF5 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57354688; called by muse, mutect2, varscan2
- SEC14L3 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307179; called by muse, mutect2
- BOP1 | c.490C>G p.R164G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by mutect2, varscan2
